HCMI case HCM-CSHL-0382-C19 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ee0c283-701b-47ac-bc3a-30f45e5c4eb2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 68.0 years (24,847 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 6 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 38 days; Days to treatment end: 219 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 765 days (2.1 years).
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 905 days (2.5 years); Days to treatment end: 914 days (2.5 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 68.7 years (25,086 days); Days to diagnosis: 239 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Leucovorin; Treatment intent type: Maintenance Therapy; Treatment outcome: Treatment Ongoing.

Follow-up (2 entries)
- Days to follow up: 987 days (2.7 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 912.

Molecular and laboratory tests
- BRAF (IHC): Negative.
- BRAF mutation, nos: Negative.
- CEA: 5.8 ng/mL.
- KRAS mutation, nos: Negative.
- MLH1 (IHC): Negative.
- MLH1 methylation: Equivocal.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 21 days; Days to risk factor: 21 days; Risk factors: Colon Polyps.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps / Diverticulosis.
- Timepoint category: Initial Diagnosis; Weight: 68.3 kg; Height: 157.4 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0382-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0382-C19-01A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 7.
  Slide HCM-CSHL-0382-C19-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 8.
- Sample HCM-CSHL-0382-C19-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0382-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0382-C19-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
